Surgical pathology report (de-identified scan), TCGA case TCGA-DD-A39W, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-A39W-01A (Primary Tumor).

1 CD 0-3
Carcinoma, hepatocellular, NOS 8170/3
Site: liver c22.0 lw 7/22/11

Patient Key

Surgical date:

TISSUE DESCRIPTION:

Portion right lobe liver (16 x 12 x 5.5 cm) with attached gallbladder (together weighing 575 grams) and separately submitted choledochal lymph node (2.5 x 1.5 x 1 cm). A1, B1, B2 B3, B4, B5, B6, B7, B8, B9, B10, B11, B12, B13, B14,

DIAGNOSIS:

Grade 2 hepatocellular carcinoma forming a mass, 13 x 10 x 5.0 cm. The nonneoplastic liver shows no evidence of cirrhosis. A separate fibrous nodule measuring 3.5 x 2.5 x 2.5 cm shows old granuloma, as well as hepatocellular carcinoma. The surgical resection margins are clear by at least 0.4 cm. The attached gallbladder shows cholesterolosis. A pericholedochal lymph node received with the liver specimen and a separately submitted choledochal lymph node show reactive lymphoid hyperplasia; negative for tumor.

Choledochal lymph node: All embedded.

PHOTOGRAPHED IN LAB

REVISION DESCRIPTION:

SIGNED OUT ACCIDENTALLY, CORRECTION WAS NEEDED.

....ORIGINAL FOLLOWS....

A1, B1, B2, B3, B4, B5, B6, B7, B8, B9, B10, B11, B12, B13, B14

DIAGNOSIS:

Grade 2 hepatocellular carcinoma forming a mass, 13 x 10 5.0 cm. The nonneoplastic liver shows no evidence of cirrhosis. A separate fibrous nodule measuring 3.5 x 2.5 x 2.5 cm shows old granuloma, as well as hepatocellular carcinoma. The surgical resection margins are clear by at least 0.4 cm. The attached gallbladder shows cholesterolosis. A pericholedocahl lymph node received with the liver specimen and a separately submitted choledochal lymph node show reactive lymphoid hyperplasia; negative for tumor.

Choledochal lymph node: All embedded.

ADDENDUM:

Special stains for acid fast bacilli and fungi are performed on the sections of old granuloma.

They are negative.

IN/PA Discrepancy		X

Source: NCI Genomic Data Commons file c54c869e-c666-43e6-8a4f-1e2412d1797e (TCGA-DD-A39W.3EE9248B-64B4-4B76-A427-73C254D6489D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).